Somatic mutation profile of tumor specimen TCGA-HZ-A49H-01A (aliquot TCGA-HZ-A49H-01A-11D-A26I-08) from TCGA case TCGA-HZ-A49H, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 68.1 years (24,891 days).
Specimen TCGA-HZ-A49H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9701ef15-c1ce-4f39-b858-9ac93ccb64d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A49H-10A (Blood Derived Normal), aliquot TCGA-HZ-A49H-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b865b50-0635-4e13-9405-65ac2540402c

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/138 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ATP10B | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 72/637 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV100514004; called by muse, mutect2, varscan2
- BRINP3 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 36/733 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66513568; called by muse, mutect2
- CDK5RAP2 | c.1415T>G p.L472W | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100575024; called by muse, mutect2, varscan2
- CPNE6 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773443699, COSV53743741; called by muse, mutect2
- FAM47A | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as rs776209186, COSV60494163; called by muse, mutect2, varscan2
- GRIK3 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 86/543 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs569112734, COSV66144226; called by muse, mutect2, varscan2
- CCDC93 | c.1178del p.N393Mfs*4 | Frame Shift Del (DEL) | VAF 154/1268 reads (12%) | called by mutect2, pindel, varscan2
- ZBTB22 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 18/646 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.04); called by muse, mutect2
- DOT1L | c.1266C>T p.P422= | Silent (SNP) | VAF 77/490 reads (16%) | catalogued as rs373787443; called by muse, mutect2, varscan2
- PSD | c.2037C>T p.I679= | Silent (SNP) | VAF 32/695 reads (5%) | catalogued as COSV50063287; called by muse, mutect2
